CPTAC case SC-0515 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3fb228ea-2e2c-4910-b452-9cfd904e981d

Demographics
Sex at birth: male; Age: 90 years or older (exact value withheld by GDC); Vital status: Alive.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of trunk; Age at diagnosis: 90 years or older (exact value withheld by GDC); AJCC staging edition: 8th; AJCC pathologic T: T4a; AJCC pathologic N: NX; AJCC pathologic M: M0; Progression or recurrence: no; Days to last follow up: 61 days; Clark level: IV.
   Pathology details: Breslow thickness: 7.5.

Biospecimens (2 samples)
- Sample S-2101-001989: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Frozen; Initial weight: 77 mg; Method of sample procurement: Tumor Resection.
- Sample S-2101-001990: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Frozen; Initial weight: 85 mg; Method of sample procurement: Tumor Resection.
